Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MK-01A (Primary Tumor).

FINAL DIAGNOSIS:

UTERUS WITH BILATERAL ADNEXA (500 GRAMS), TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- 8560/3 divided into - Endometrioid adenocarcinoma
- A. ADENOSQUAMOUS CARCINOMA POORLY DIFFERENTIATED, OF ENDOMETRIUM, NUCLEAR GRADE 3 (see comment).
- B. TUMOR INVOLVES THE ENTIRE ENDOMETRIAL CAVITY, PENETRATES UP TO 30% IF THE MYOMETRIUM.
- C. TUMOR EXTENDS CIRCUMFERENTIALLY TO ENDOCERVICAL CANAL AND PENETRATES INTO THE ENDOCERVICAL WALL, UP TO 0.1 CM FROM THE ENDOCERVICAL SEROSA.
- D. LYMPHOVASCULAR INVOLVEMENT IS SEEN.
- E. ADENOMYOSIS.
- F. RIGHT AND LEFT OVARIES WITH PHYSIOLOGICAL CHANGES.
- G. RIGHT FALLOPIAN TUBE, NOT REMARKABLE
- H. LEFT FALLOPIAN TUBE WITH FOCAL ATYPICAL EPITHELIAL HYPERPLASIA

COMMENT:

Positive ER, Vimentin and negative CEA immunostains confirm the above diagnosis.
P16 immunostain is focally positive. Please refer [REDACTED]
Pelvic wash cytology [REDACTED] is interpreted as negative.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE:

Adenosquamous carcinoma

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Poorly differentiated (FIGO 3)

ARCHITECTURAL GRADE:

Poorly differentiated

NUCLEAR GRADE:

Grade 3

TUMOR SIZE:

Maximum dimension: 8 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 100 %, Posterior endomyometrium: 100 %

DEPTH OF INVASION**:

Less than 1/2 thickness of myometrium

STRUCTURES INVOLVED:

Endocervical glands, Cervical stroma

MARGINS OF RESECTION:

Vaginal margin is negative for tumor

ANGIOLYMPHATIC INVASION:

Yes

OTHER:

(epithelial, smooth muscle, others), Adenomyosis

LYMPH NODES POSITIVE:

Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 0

T STAGE, PATHOLOGIC:

pT2b

N STAGE, PATHOLOGIC:

pNX

M STAGE, PATHOLOGIC:

PMX

FIGO STAGE:

IIB

1CD-0-3

Path Adenosquamous carcinoma 8560/3
CQCF MKA - Endometrioid adenocarcinoma 8380/3
Site: endometrium C54.1
for 5/3/11

Source: NCI Genomic Data Commons file 8e731419-bde3-410e-b95d-f1882b87644b (TCGA-BG-A0MK.9D631FCB-78A9-4CA9-A033-D66CB78D8CA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).